Somatic mutation profile of tumor specimen TCGA-C5-A7CL-01A (aliquot TCGA-C5-A7CL-01A-11D-A32I-09) from TCGA case TCGA-C5-A7CL, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IIIB; Tumor grade: G2; Age at diagnosis: 48.9 years (17,869 days).
Specimen TCGA-C5-A7CL-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 02fdc4e3-bfe1-4db8-bae7-dedbb143220c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-C5-A7CL-10A (Blood Derived Normal), aliquot TCGA-C5-A7CL-10A-01D-A32I-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b73bea52-dd09-4e33-ac55-9045d4cfca64

The open-access MAF lists 127 somatic variants for this specimen: 94 protein-altering or splice-affecting, 31 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 83, Silent 31, Nonsense Mutation 5, Intron 2, Frame Shift Del 2, Splice Region 1, In Frame Del 1, Frame Shift Ins 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCA12 | c.2334A>G p.T778= (on ENST00000272895 / NM_173076.3; = p.T460= on NM_015657.3) | Splice Region (SNP) | VAF 7/48 reads (15%) | catalogued as COSV55970203; called by muse, mutect2, varscan2
- ABHD8 | c.1045G>A p.E349K | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.453); catalogued as COSV56045858; called by muse, mutect2, varscan2
- ADAMTS7 | c.4688G>A p.R1563Q | Missense Mutation (SNP) | VAF 26/87 reads (30%) | SIFT tolerated (0.44); PolyPhen benign (0.082); catalogued as rs768246977, COSV66308856; called by muse, mutect2, varscan2
- ADGRV1 | c.12868C>T p.R4290C | Missense Mutation (SNP) | VAF 25/50 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs775861115, COSV67982880; called by muse, mutect2, varscan2
- AP000721.1 | c.36G>C p.L12F | Missense Mutation (SNP) | VAF 24/57 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV58478939; called by muse, mutect2, varscan2
- ARHGAP4 | c.1681+1G>C p.X561_splice | Splice Site (SNP) | VAF 6/20 reads (30%) | catalogued as COSV61686699; called by muse, mutect2, varscan2
- ARHGEF9 | c.757T>A p.L253M | Missense Mutation (SNP) | VAF 13/32 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53642253; called by muse, mutect2, varscan2
- ARPC2 | c.57C>G p.F19L | Missense Mutation (SNP) | VAF 11/53 reads (21%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as COSV55285957; called by muse, mutect2, varscan2
- ASTE1 | c.235G>C p.D79H | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53909892; called by muse, mutect2, varscan2
- ATP2B2 | c.1340G>A p.G447E (on ENST00000352432; = p.G413E on NM_001683.5) | Missense Mutation (SNP) | VAF 4/9 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59504452; called by muse, mutect2, varscan2
- ATP2B3 | c.761C>G p.S254* | Nonsense Mutation (SNP) | VAF 10/35 reads (29%) | catalogued as COSV54856977; called by muse, mutect2, varscan2
- AUH | c.253G>A p.E85K | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT tolerated (0.38); PolyPhen benign (0.018); catalogued as rs940124410, COSV57865173; called by muse, mutect2, varscan2
- BBX | c.833C>G p.S278* | Nonsense Mutation (SNP) | VAF 6/54 reads (11%) | catalogued as COSV57891519; called by muse, mutect2, varscan2
- BIRC6 | c.2573C>T p.S858L | Missense Mutation (SNP) | VAF 19/64 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV70203839; called by muse, mutect2, varscan2
- BUB1 | c.2029C>T p.R677C | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as rs867863036, COSV57062533; called by muse, mutect2, varscan2
- BUB1B | c.863C>T p.S288F | Missense Mutation (SNP) | VAF 24/62 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as COSV55015421; called by muse, mutect2, varscan2
- C5orf34 | c.168G>C p.R56S | Missense Mutation (SNP) | VAF 10/53 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60931506; called by muse, mutect2, varscan2
- CACNA1G | c.1825G>A p.E609K | Missense Mutation (SNP) | VAF 6/76 reads (8%) | SIFT tolerated (0.4); PolyPhen benign (0.017); catalogued as COSV100662317; called by muse, mutect2
- CADM3 | c.245G>A p.R82Q (on ENST00000368125 / NM_001127173.3; = p.R116Q on NM_021189.5) | Missense Mutation (SNP) | VAF 9/70 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63684047, COSV63685846; called by muse, mutect2, varscan2
- CCPG1 | c.121G>A p.E41K | Missense Mutation (SNP) | VAF 25/90 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.773); catalogued as COSV60527066; called by muse, mutect2, varscan2
- CD101 | c.1247C>T p.S416F | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT tolerated (0.05); PolyPhen benign (0.011); catalogued as COSV56717799; called by muse, mutect2, varscan2
- CELF6 | c.401G>A p.R134Q | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as rs138690830; called by muse, mutect2, varscan2
- CLSTN2 | c.2302C>T p.R768W | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.72); catalogued as rs542507966, COSV71719536; called by muse, mutect2, varscan2
- COL27A1 | c.718G>A p.D240N | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as COSV61929576; called by muse, mutect2, varscan2
- COL3A1 | c.2110G>A p.E704K | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.057); catalogued as rs863223362, COSV58591872; ClinVar: benign / uncertain significance; called by muse, mutect2, varscan2
- CYB5R1 | c.334C>G p.L112V | Missense Mutation (SNP) | VAF 41/132 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.899); catalogued as COSV65917165; called by muse, mutect2, varscan2
- DACH1 | c.1126G>A p.G376S (on ENST00000619232 / NM_001366712.1; = p.G376R on NM_080759.6) | Missense Mutation (SNP) | VAF 17/42 reads (40%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.41); catalogued as COSV57492873; called by muse, mutect2, varscan2
- DDX43 | c.1326G>C p.L442F | Missense Mutation (SNP) | VAF 14/55 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV64813499; called by muse, mutect2, varscan2
- DOCK11 | c.631G>A p.E211K | Missense Mutation (SNP) | VAF 24/67 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV52244897; called by muse, mutect2, varscan2
- DYM | c.1390T>G p.L464V | Missense Mutation (SNP) | VAF 17/68 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53989918; called by muse, mutect2, varscan2
- EFNB2 | c.467G>A p.R156K | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT tolerated (0.86); PolyPhen benign (0.001); catalogued as COSV55366674; called by muse, mutect2, varscan2
- EFS | c.1033C>A p.P345T | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.062); catalogued as COSV53733754; called by muse, mutect2
- F2RL2 | c.871G>A p.A291T | Missense Mutation (SNP) | VAF 42/57 reads (74%) | SIFT tolerated (0.45); PolyPhen benign (0.027); catalogued as COSV56970674, COSV56971664; called by muse, mutect2, varscan2
- FAM177B | c.6G>C p.E2D | Missense Mutation (SNP) | VAF 9/111 reads (8%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.537); catalogued as COSV100680434, COSV62601125; called by muse, mutect2
- FASTKD1 | c.142G>C p.D48H | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT tolerated (0.38); PolyPhen benign (0.025); catalogued as COSV70007141; called by muse, mutect2, varscan2
- FBN2 | c.2149C>T p.R717C | Missense Mutation (SNP) | VAF 5/44 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as rs766945762, COSV52503308; called by mutect2, varscan2
- FECH | c.782C>T p.S261F | Missense Mutation (SNP) | VAF 18/54 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.869); catalogued as HM080005, COSV50492080; called by muse, mutect2, varscan2
- GAB4 | c.1381C>A p.H461N | Missense Mutation (SNP) | VAF 16/58 reads (28%) | SIFT tolerated (0.33); PolyPhen benign (0.007); catalogued as COSV68754762; called by muse, mutect2, varscan2
- GABBR1 | c.2206C>T p.R736W | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as rs767733339, COSV100589510, COSV63543960; called by muse, mutect2, varscan2
- GNB5 | c.256C>T p.R86W (on ENST00000261837 / NM_016194.4; = p.R44W on NM_006578.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.336); catalogued as rs1197715092, COSV55900586; called by muse, mutect2, varscan2
- HAPLN2 | c.565G>C p.E189Q | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.985); catalogued as COSV54815473, COSV54815988, COSV99660863; called by muse, mutect2
- HERC5 | c.3043G>A p.E1015K | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.065); catalogued as rs751293985, COSV52043082; called by muse, mutect2, varscan2
- HUWE1 | c.1931G>A p.R644Q | Missense Mutation (SNP) | VAF 40/129 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as rs937590528, COSV53358505; called by muse, mutect2, varscan2
- IL19 | c.527C>T p.S176L | Missense Mutation (SNP) | VAF 15/93 reads (16%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.01); catalogued as COSV54284350; called by muse, mutect2, varscan2
- INSL5 | c.178G>C p.E60Q | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.958); catalogued as rs780878572, COSV58788496; called by muse, mutect2, varscan2
- ITIH4 | c.2725G>A p.E909K | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT tolerated (0.64); PolyPhen benign (0.015); catalogued as COSV56577217, COSV99820092; called by muse, mutect2, varscan2
- KAT5 | c.464C>T p.S155L | Missense Mutation (SNP) | VAF 16/43 reads (37%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as COSV57729532; called by muse, mutect2, varscan2
- LRP1B | c.1661A>G p.N554S | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0.152); catalogued as COSV67257086; called by muse, mutect2, varscan2
- MED13L | c.908G>A p.G303D | Missense Mutation (SNP) | VAF 16/45 reads (36%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.657); catalogued as COSV56126626, COSV56128568; called by muse, mutect2, varscan2
- MGAT3 | c.627C>G p.I209M | Missense Mutation (SNP) | VAF 12/26 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV57864285; called by muse, mutect2, varscan2
- MXRA8 | c.1290C>G p.I430M | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.401); catalogued as rs367562728, COSV58511435; called by muse, mutect2, varscan2
- NR1D1 | c.570C>G p.F190L | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.436); catalogued as COSV52845264; called by muse, mutect2, varscan2
- NTRK3 | c.485T>C p.F162S | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV58136067; called by muse, mutect2, varscan2
- OR6C76 | c.585G>C p.M195I | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT tolerated, low confidence (0.49); PolyPhen benign (0.045); catalogued as COSV60389651; called by mutect2, varscan2
- PIGQ | c.1166C>G p.S389W | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV50318330, COSV99216470; called by muse, mutect2, varscan2
- PRKCG | c.1627G>A p.V543I | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.593); catalogued as COSV54731148; called by muse, mutect2, varscan2
- PRRX1 | c.257C>T p.S86L | Missense Mutation (SNP) | VAF 16/65 reads (25%) | SIFT tolerated (0.08); PolyPhen benign (0.011); catalogued as COSV53417277; called by muse, mutect2, varscan2
- PTEN | c.686C>G p.S229* | Nonsense Mutation (SNP) | VAF 22/52 reads (42%) | catalogued as CM110118, COSV64290316, COSV64291916, COSV64310910; called by muse, mutect2, varscan2
- PTPRF | c.3153G>C p.Q1051H | Missense Mutation (SNP) | VAF 3/20 reads (15%) | SIFT tolerated (0.16); PolyPhen benign (0.013); catalogued as COSV63447501; called by muse, mutect2
- PUF60 | c.178A>G p.T60A | Missense Mutation (SNP) | VAF 3/27 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.184); catalogued as COSV57650259; called by muse, mutect2
- RARB | c.461C>T p.S154F (on ENST00000383772 / NM_001290216.2; = p.S147F on NM_000965.5 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV58069841; called by muse, mutect2, varscan2
- RASGRP2 | c.550C>T p.H184Y | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.884); catalogued as COSV62450450; called by muse, mutect2, varscan2
- RYR1 | c.8170G>A p.E2724K | Missense Mutation (SNP) | VAF 18/45 reads (40%) | SIFT deleterious (0.03); PolyPhen benign (0.05); catalogued as CM096746, COSV62105927; called by muse, mutect2, varscan2
- SBF1 | c.1684C>T p.R562W | Missense Mutation (SNP) | VAF 20/45 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1301087859, COSV62369702; called by muse, mutect2, varscan2
- SLC12A5 | c.583C>G p.L195V (on ENST00000454036 / NM_001134771.2; = p.L172V on NM_020708.5) | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54799146; called by mutect2, varscan2
- SLC17A7 | c.1308C>G p.I436M | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV55549047; called by muse, mutect2, varscan2
- SLC45A2 | c.798C>A p.Y266* | Nonsense Mutation (SNP) | VAF 10/48 reads (21%) | catalogued as CM101005, COSV56874260; called by muse, mutect2, varscan2
- SLC9A2 | c.2157C>G p.F719L | Missense Mutation (SNP) | VAF 13/52 reads (25%) | SIFT tolerated (0.72); PolyPhen benign (0.003); catalogued as rs1337408612, COSV52135850; called by muse, mutect2, varscan2
- SLCO2A1 | c.1437G>C p.M479I | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT tolerated (0.72); PolyPhen benign (0.001); catalogued as COSV60486098; called by muse, mutect2, varscan2
- SPARCL1 | c.184G>A p.D62N | Missense Mutation (SNP) | VAF 18/35 reads (51%) | SIFT tolerated (0.49); PolyPhen benign (0.003); catalogued as COSV56805542; called by muse, mutect2, varscan2
- STK11 | c.332T>A p.I111N | Missense Mutation (SNP) | VAF 13/27 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58826928; called by muse, mutect2, varscan2
- STK11 | c.881C>T p.P294L | Missense Mutation (SNP) | VAF 31/71 reads (44%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.959); catalogued as COSV58823474; called by muse, mutect2, varscan2
- TCHH | c.2689G>C p.E897Q | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.024); catalogued as COSV64276856; called by muse, mutect2
- TENM4 | c.5912C>G p.S1971* | Nonsense Mutation (SNP) | VAF 5/24 reads (21%) | catalogued as COSV53618297, COSV53655718; called by muse, mutect2, varscan2
- TPR | c.5857G>C p.E1953Q | Missense Mutation (SNP) | VAF 36/75 reads (48%) | SIFT deleterious (0.04); PolyPhen benign (0.039); catalogued as COSV66603782; called by muse, mutect2, varscan2
- TSPAN11 | c.100G>A p.V34I | Missense Mutation (SNP) | VAF 20/83 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.127); catalogued as rs750835880, COSV53819328; called by muse, mutect2, varscan2
- UBQLN1 | c.1642C>G p.Q548E | Missense Mutation (SNP) | VAF 13/74 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV57408865; called by muse, mutect2, varscan2
- UGT1A1 | c.206G>A p.R69K | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV59395224; called by muse, mutect2, varscan2
- UPF3B | c.1222G>C p.E408Q (on ENST00000276201 / NM_080632.3; = p.E395Q on NM_023010.3) | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT tolerated (0.07); PolyPhen benign (0.261); catalogued as COSV52231047; called by muse, mutect2, varscan2
- USF3 | c.5713G>C p.D1905H | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV57071347, COSV57075993; called by muse, mutect2, varscan2
- USP24 | c.7596G>C p.Q2532H | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.948); catalogued as COSV53774895; called by muse, mutect2, varscan2
- USP32 | c.1330G>A p.E444K | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT tolerated (0.41); PolyPhen benign (0.027); catalogued as rs376352735; called by muse, mutect2, varscan2
- VSTM2L | c.409G>A p.E137K | Missense Mutation (SNP) | VAF 13/52 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs771171569, COSV65096406; called by muse, mutect2, varscan2
- ZFP41 | c.112G>C p.E38Q | Missense Mutation (SNP) | VAF 17/62 reads (27%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as COSV58087961; called by muse, mutect2, varscan2
- ZNF207 | c.1252A>T p.M418L | Missense Mutation (SNP) | VAF 19/49 reads (39%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.138); catalogued as COSV58301326; called by muse, mutect2, varscan2
- ZNF26 | c.571G>C p.V191L | Missense Mutation (SNP) | VAF 21/74 reads (28%) | SIFT tolerated (0.54); PolyPhen possibly damaging (0.482); catalogued as COSV60807113; called by muse, mutect2, varscan2
- ZNF597 | c.133G>C p.E45Q | Missense Mutation (SNP) | VAF 15/55 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.604); catalogued as COSV57083488, COSV57085251; called by muse, mutect2, varscan2
- ZNF653 | c.1241C>T p.T414M | Missense Mutation (SNP) | VAF 18/44 reads (41%) | SIFT tolerated (0.11); PolyPhen benign (0.306); catalogued as rs199756281, COSV53404177; called by muse, mutect2, varscan2
- COBL | c.464_465del p.V155Afs*19 | Frame Shift Del (DEL) | VAF 9/29 reads (31%) | called by pindel, varscan2
- GOLGA6L9 | c.376G>C p.E126Q | Missense Mutation (SNP) | VAF 24/180 reads (13%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.647); called by muse, mutect2
- IGHV4-59 | c.113C>G p.S38C | Missense Mutation (SNP) | VAF 16/228 reads (7%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.886); called by muse, mutect2
- PSMB10 | c.18_29delinsC p.E7Gfs*51 | Frame Shift Del (DEL) | VAF 15/51 reads (29%) | called by pindel, varscan2*
- SAPCD2 | c.700_702del p.E234del | In Frame Del (DEL) | VAF 7/27 reads (26%) | called by mutect2, pindel, varscan2
- SOCS2 | c.158dup p.M53Ifs*4 | Frame Shift Ins (INS) | VAF 5/36 reads (14%) | called by mutect2, pindel, varscan2
- CFAP100 | c.1308G>C p.L436= | Silent (SNP) | VAF 14/62 reads (23%) | catalogued as COSV61504094; called by muse, mutect2, varscan2
- CIITA | c.2683C>T p.L895= | Silent (SNP) | VAF 10/35 reads (29%) | catalogued as rs776323785, COSV60860552; called by muse, mutect2, varscan2
- CPT1B | c.660G>A p.Q220= | Silent (SNP) | VAF 4/23 reads (17%) | catalogued as COSV56418262; called by muse, mutect2, varscan2
- DAXX | c.1095G>C p.R365= | Silent (SNP) | VAF 6/22 reads (27%) | catalogued as COSV56471717; called by muse, mutect2, varscan2
- FCGBP | c.2526G>A p.P842= | Silent (SNP) | VAF 11/24 reads (46%) | catalogued as rs1331568666; called by muse, mutect2, varscan2
- FOXI1 | c.276G>A p.Q92= | Silent (SNP) | VAF 12/31 reads (39%) | catalogued as COSV60388603; called by muse, mutect2, varscan2
- FRMD4A | c.903G>A p.P301= | Silent (SNP) | VAF 17/54 reads (31%) | catalogued as rs200042373, COSV52732275; called by muse, mutect2, varscan2
- GRIN2B | c.2925G>C p.L975= | Silent (SNP) | VAF 19/43 reads (44%) | catalogued as COSV74207145; called by muse, mutect2, varscan2
- HCFC2 | c.135C>T p.I45= | Silent (SNP) | VAF 9/25 reads (36%) | catalogued as COSV57559826; called by muse, mutect2, varscan2
- HIP1 | c.954C>T p.A318= | Silent (SNP) | VAF 7/45 reads (16%) | catalogued as rs1554494870, COSV61189755; called by muse, mutect2, varscan2
- IFNA8 | c.64C>T p.L22= | Silent (SNP) | VAF 20/99 reads (20%) | catalogued as COSV66504830; called by muse, mutect2, varscan2
- KCNH8 | c.43C>T p.L15= | Silent (SNP) | VAF 22/50 reads (44%) | catalogued as COSV60456008, COSV60472373; called by muse, mutect2, varscan2
- KCNN1 | c.633G>A p.A211= | Silent (SNP) | VAF 10/38 reads (26%) | catalogued as rs565285734, COSV55840953; called by muse, mutect2, varscan2
- KCNT1 | c.1359C>T p.I453= (on ENST00000488444; = p.I472= on NM_020822.3) | Silent (SNP) | VAF 23/54 reads (43%) | catalogued as COSV53707533; called by muse, mutect2, varscan2
- LCT | c.4410G>C p.L1470= | Silent (SNP) | VAF 4/34 reads (12%) | catalogued as COSV51553290, COSV51559513; called by muse, mutect2
- MAU2 | c.468G>A p.T156= | Silent (SNP) | VAF 9/23 reads (39%) | catalogued as rs199781947, COSV53237356; called by muse, mutect2, varscan2
- MGAT3 | c.168C>T p.V56= | Silent (SNP) | VAF 16/44 reads (36%) | catalogued as COSV57867524; called by muse, mutect2, varscan2
- MORC2 | c.2802G>C p.L934= (on ENST00000397641 / NM_001303256.3; = p.L872= on NM_014941.3) | Silent (SNP) | VAF 18/63 reads (29%) | catalogued as COSV99310235; called by muse, mutect2, varscan2
- MYRIP | c.2328G>T p.V776= | Silent (SNP) | VAF 4/50 reads (8%) | called by muse, mutect2
- OR6C76 | c.771G>A p.V257= | Silent (SNP) | VAF 5/25 reads (20%) | catalogued as COSV60389663; called by muse, mutect2, varscan2
- PNO1 | c.390G>C p.L130= | Silent (SNP) | VAF 12/43 reads (28%) | catalogued as COSV54562480; called by muse, mutect2, varscan2
- PTCHD3 | c.453G>A p.A151= | Silent (SNP) | VAF 6/36 reads (17%) | catalogued as rs141109338; called by mutect2, varscan2
- SEC24A | c.1137C>G p.L379= | Silent (SNP) | VAF 14/44 reads (32%) | catalogued as COSV59748831; called by muse, mutect2, varscan2
- SLC35E1 | c.1116C>G p.L372= | Silent (SNP) | VAF 18/53 reads (34%) | catalogued as COSV68736311, COSV68736523; called by muse, mutect2, varscan2
- STK11 | c.333C>T p.I111= | Silent (SNP) | VAF 13/29 reads (45%) | catalogued as rs1555737428, COSV58820954; ClinVar: likely benign; called by muse, mutect2, varscan2
- TAP2 | c.231C>T p.V77= | Silent (SNP) | VAF 32/90 reads (36%) | catalogued as COSV66488184; called by muse, mutect2, varscan2
- TGFB1I1 | c.1086C>T p.S362= (on ENST00000394863 / NM_001042454.3; = p.S345= on NM_015927.4) | Silent (SNP) | VAF 8/15 reads (53%) | catalogued as COSV62358918; called by muse, mutect2, varscan2
- TMEM167B | c.90C>G p.L30= | Silent (SNP) | VAF 20/65 reads (31%) | catalogued as COSV57808504; called by muse, mutect2, varscan2
- TSPEAR | c.1317G>A p.A439= | Silent (SNP) | VAF 16/52 reads (31%) | catalogued as rs782043381, COSV59973686; ClinVar: likely benign; called by muse, mutect2, varscan2
- USP42 | c.1446G>A p.S482= | Silent (SNP) | VAF 17/56 reads (30%) | catalogued as rs1183817805, COSV60363226; called by muse, mutect2, varscan2
- USP51 | c.141G>A p.A47= | Silent (SNP) | VAF 19/82 reads (23%) | catalogued as COSV72351543; called by muse, mutect2, varscan2
- CIRBP | c.-7+627G>C | Intron (SNP) | VAF 10/43 reads (23%) | catalogued as COSV58011895; called by muse, mutect2, varscan2
- LEPR | c.2674-3035C>T | Intron (SNP) | VAF 14/60 reads (23%) | catalogued as rs762314477, COSV62750563; called by muse, mutect2, varscan2
